Somatic mutation profile of tumor specimen TCGA-KO-8417-01A (aliquot TCGA-KO-8417-01A-11D-2310-10) from TCGA case TCGA-KO-8417, project TCGA-KICH (Kidney Chromophobe). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 30.5 years (11,139 days).
Specimen TCGA-KO-8417-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03c7a0ef-8d41-465a-9233-9f2790f44317.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KO-8417-11A (Solid Tissue Normal), aliquot TCGA-KO-8417-11A-01D-2311-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6febba1f-8737-4bf3-9624-9cc5a657817b

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 9, Silent 4, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS2 | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779902229, COSV99202213; called by muse, mutect2, varscan2
- AJAP1 | c.646G>C p.V216L | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT tolerated (0.1); PolyPhen benign (0.124); catalogued as COSV100981709; called by muse, mutect2, varscan2
- CAPN11 | c.152G>T p.G51V | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101291884; called by muse, mutect2
- CFAP47 | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 12/183 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.065); catalogued as rs768810184, COSV52889672; called by muse, mutect2
- MUC16 | c.41506G>A p.G13836S | Missense Mutation (SNP) | VAF 45/200 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.994); catalogued as COSV101109895; called by muse, mutect2, varscan2
- PDZD11 | c.418C>A p.H140N | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV99333664; called by muse, mutect2
- PPP1R9A | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56880598, COSV56912818; called by muse, mutect2, varscan2
- YLPM1 | c.3325C>T p.R1109* | Nonsense Mutation (SNP) | VAF 6/56 reads (11%) | catalogued as COSV53110855; called by muse, mutect2, varscan2
- ZBTB43 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as COSV65094616; called by muse, mutect2, varscan2
- P4HB | c.1524_1525del p.*509Ifs*31 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | called by mutect2, pindel, varscan2
- ZNF658 | c.276A>T p.E92D | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- LIPC | c.585C>T p.A195= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs149322349; called by muse, mutect2, varscan2
- PPP6C | c.627C>T p.P209= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV101001147; called by muse, mutect2, varscan2
- PROX1 | c.1225C>T p.L409= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV54784800, COSV99799404; called by muse, mutect2, varscan2
- RPS6KA6 | c.1209T>C p.P403= | Silent (SNP) | VAF 112/143 reads (78%) | catalogued as COSV99424718; called by muse, mutect2, varscan2
